Somatic mutation profile of tumor specimen MP2PRT-PAVXZY-TMP1-A (aliquot MP2PRT-PAVXZY-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAVXZY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,002 days).
Specimen MP2PRT-PAVXZY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea7b793-1c9d-4a54-9b1f-c0ce74c5f0a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXZY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXZY-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e17b848d-909e-4ae7-adb3-c81ca048ec98

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB1 | c.2165C>T p.A722V (on ENST00000360697 / NM_001346687.2; = p.A682V on NM_001112.4) | Missense Mutation (SNP) | VAF 21/575 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1323703791, COSV62345168; ClinVar: pathogenic; called by muse, mutect2
- GNB1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557898800; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEBPZ | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99135399; called by muse, mutect2
- DNAH9 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); catalogued as COSV52376139; called by muse, mutect2
- ELFN1 | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 51/686 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1439363867; called by muse, mutect2
- IL3RA | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs766258222, COSV100452277; called by muse, mutect2
- LAMA2 | c.910-1G>A p.X304_splice | Splice Site (SNP) | VAF 27/196 reads (14%) | catalogued as CS151379; called by muse, mutect2, varscan2
- MPDZ | c.4807+1G>A p.X1603_splice | Splice Site (SNP) | VAF 25/190 reads (13%) | catalogued as COSV59924573; called by muse, mutect2, varscan2
- NOL6 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs770885820; called by muse, mutect2, varscan2
- PCSK7 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as rs1214410070; called by muse, mutect2, varscan2
- ARL6 | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRM3 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- GCFC2 | c.2249T>A p.I750N | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2
- H2AZ2 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.151); called by muse, mutect2
- HECTD1 | c.6746G>C p.G2249A | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HSPG2 | c.3494C>G p.S1165* | Nonsense Mutation (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- IGHV3-43 | chr14:106470257 ACTGTGTATCTT>GGAA | Missense Mutation (DEL) | VAF 29/89 reads (33%) | called by pindel, varscan2*
- INKA1 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA3 | c.2142G>T p.M714I | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- ITGA3 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.207); called by muse, mutect2
- NCAPD3 | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PODXL2 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.015); called by muse, mutect2
- RABGAP1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2
- TRDD2 | c.8_9insG p.Y3* | Nonsense Mutation (INS) | VAF 44/134 reads (33%) | called by mutect2, pindel*, varscan2
- TXNRD1 | c.1648G>C p.E550Q (on ENST00000525566 / NM_001093771.3; = p.E452Q on NM_003330.4) | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2
- TXNRD1 | c.1649A>T p.E550V (on ENST00000525566 / NM_001093771.3; = p.E452V on NM_003330.4) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- ZBTB41 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF318 | c.5302G>A p.E1768K | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.011); called by muse, mutect2
- HNRNPL | c.462G>C p.V154= | Silent (SNP) | VAF 51/341 reads (15%) | called by muse, mutect2, varscan2
- LFNG | c.561C>G p.R187= (on ENST00000222725 / NM_001040167.2; = p.R58= on NM_002304.2) | Silent (SNP) | VAF 18/444 reads (4%) | called by muse, mutect2
- OR51G2 | c.831C>A p.V277= | Silent (SNP) | VAF 19/458 reads (4%) | catalogued as COSV58993341; called by muse, mutect2
- OR51G2 | c.654C>G p.L218= | Silent (SNP) | VAF 15/483 reads (3%) | called by muse, mutect2
- PIK3C2A | c.3042C>G p.L1014= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- POLM | c.1059C>G p.R353= | Silent (SNP) | VAF 17/478 reads (4%) | called by muse, mutect2
- SAMD4A | c.1320G>A p.L440= | Silent (SNP) | VAF 24/658 reads (4%) | called by muse, mutect2
- SFSWAP | c.1011T>C p.S337= | Silent (SNP) | VAF 185/464 reads (40%) | called by muse, mutect2, varscan2
- SH3BP5 | c.768G>A p.E256= | Silent (SNP) | VAF 38/467 reads (8%) | called by muse, mutect2
- TRAV8-6 | chr14:21979120 ins AGGCC | 3'Flank (INS) | VAF 22/208 reads (11%) | called by mutect2, pindel
